Somatic mutation profile of tumor specimen 0DSMY3 from CCDI case PBCILI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 9.3 years (3,405 days).
Specimen 0DSMY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 877156d8-c81a-432e-b082-e85c3858c88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSMYG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf55e233-62a1-40ef-be68-a38ae51de5fc

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DLGAP2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780224074; called by muse, mutect2
- GPR174 | c.567C>T p.G189= | Silent (SNP) | VAF 17/258 reads (7%) | catalogued as rs141253543; called by muse, mutect2
- KIF16B | c.3498+2884T>C | Intron (SNP) | VAF 72/544 reads (13%) | catalogued as rs949979271; called by muse, mutect2, varscan2
